Somatic mutation profile of tumor specimen 0DYB0Y from CCDI case PBCSEZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 0.8 years (293 days).
Specimen 0DYB0Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2bd5eed-4245-4110-b856-0599e021c621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYB0N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26579ef5-39da-468c-a10d-96b3782978a0

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNIP1 | c.23A>G p.H8R | Missense Mutation (SNP) | VAF 84/623 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 28/1140 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- SMC5 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 34/1312 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- STEAP4 | c.524T>G p.L175R | Missense Mutation (SNP) | VAF 67/1806 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TNXB | c.9840C>T p.S3280= (on ENST00000647633; = p.S3033= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/721 reads (3%) | catalogued as rs763345443, COSV64475103; called by muse, mutect2
- AZGP1 | c.614-88G>A | Intron (SNP) | VAF 22/52 reads (42%) | catalogued as rs965897883; called by muse, mutect2, varscan2
- NLRC5 | c.3203+29G>A | Intron (SNP) | VAF 89/203 reads (44%) | called by muse, mutect2, varscan2
- STRAP | c.775+88T>A | Intron (SNP) | VAF 12/93 reads (13%) | called by muse, varscan2
